Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHG, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAHG-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile: -

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 1.5 cm; no angio-invasion present; no invasion of tunica albuginea; epididymis free of tumor; no invasion in rete testis; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD O3
Seminoma NOS 9061/3
Site: ① Testis NOS C62.9
JW 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file cc9b8715-c6f2-4d5c-9b07-61f906e0f2bc (TCGA-2G-AAHG.F6F33B55-54EF-46C4-8CF2-3DC7F10E3274.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).